Somatic mutation profile of tumor specimen C3L-05206-02 (aliquot CPT0345930012) from CPTAC case C3L-05206, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 78.4 years (28,619 days).
Specimen C3L-05206-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d7f508d-5a7f-43f4-b05e-4f187213705d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05206-31 (Blood Derived Normal), aliquot CPT0346080002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55bcbc75-6825-46ba-a98f-8f49f608e4fe

The open-access MAF lists 202 somatic variants for this specimen: 143 protein-altering or splice-affecting, 56 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 56, Nonsense Mutation 7, Frame Shift Ins 2, Intron 2, Splice Region 2, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 215/348 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCC11 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 104/377 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.021); catalogued as COSV62325649; called by muse, mutect2, varscan2
- APCS | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 257/533 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs866542574, COSV54818126; called by muse, mutect2, varscan2
- ATF6B | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 165/632 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV64351734; called by muse, mutect2, varscan2
- BSN | c.3028C>T p.P1010S | Missense Mutation (SNP) | VAF 128/359 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1470754384; called by muse, mutect2, varscan2
- CACNA1B | c.4498G>A p.E1500K | Missense Mutation (SNP) | VAF 86/302 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.195); catalogued as rs12377346; called by muse, mutect2, varscan2
- CALHM5 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 99/255 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.188); catalogued as COSV62068626; called by muse, mutect2, varscan2
- CCDC38 | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 89/309 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1293079824; called by muse, mutect2, varscan2
- CDHR5 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 22/441 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs202157368, COSV51564015; called by muse, mutect2
- CEACAM7 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 67/280 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); catalogued as rs782472267, COSV99137407; called by muse, mutect2, varscan2
- COL21A1 | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 98/421 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99777256; called by muse, mutect2, varscan2
- COL23A1 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 133/429 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.258); catalogued as rs371407481; called by muse, mutect2, varscan2
- COL5A1 | c.1989G>A p.R663= | Splice Region (SNP) | VAF 78/238 reads (33%) | catalogued as rs774093862; called by muse, mutect2, varscan2
- COLEC12 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 103/400 reads (26%) | catalogued as COSV68372430; called by muse, mutect2, varscan2
- CRB1 | c.1832C>T p.S611F | Missense Mutation (SNP) | VAF 272/528 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV66328793; called by muse, mutect2, varscan2
- CTTNBP2 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 234/508 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50396446; called by muse, mutect2, varscan2
- DIAPH2 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 81/257 reads (32%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.998); catalogued as rs1319821359; called by muse, mutect2, varscan2
- DNMT3L | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 82/257 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs201320726, COSV54265764; called by muse, mutect2, varscan2
- EBP | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 20/540 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV99339329, COSV99339478; called by muse, mutect2
- EPHA1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 198/687 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs45447297, COSV51977736; called by muse, mutect2, varscan2
- EPHA7 | c.2222G>A p.G741E | Missense Mutation (SNP) | VAF 117/371 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65189184, COSV65189204; called by muse, mutect2, varscan2
- FCRL4 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 268/628 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.261); catalogued as rs868440077; called by muse, mutect2, varscan2
- FLG | c.5548G>A p.E1850K | Missense Mutation (SNP) | VAF 263/524 reads (50%) | SIFT tolerated (0.98); PolyPhen benign (0.262); catalogued as rs1377089283, COSV64237232; called by muse, mutect2, varscan2
- FSIP2 | c.20215G>A p.E6739K | Missense Mutation (SNP) | VAF 115/364 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.511); catalogued as COSV58079660, COSV58098307; called by muse, mutect2, varscan2
- GALR1 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 111/320 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as rs866904324, COSV55316951; called by muse, mutect2, varscan2
- GPR179 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 83/872 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1265115446; called by muse, mutect2
- GRAMD4 | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 94/341 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1208069675; called by muse, mutect2, varscan2
- GRM5 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 138/400 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as rs756243558; called by muse, mutect2, varscan2
- GZF1 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 157/509 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.598); catalogued as COSV57634689; called by muse, mutect2, varscan2
- HRNR | c.5825G>A p.G1942E | Missense Mutation (SNP) | VAF 346/1551 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as rs1447122902; called by muse, mutect2, varscan2
- HTR2C | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 76/279 reads (27%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.24); catalogued as COSV52213050; called by muse, mutect2, varscan2
- IGHG3 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 149/436 reads (34%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.533); catalogued as rs587597693; called by muse, mutect2, varscan2
- IKZF1 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 98/419 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58788011; called by muse, mutect2, varscan2
- IL4 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 120/390 reads (31%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs772721636, COSV51502893, COSV51503198; called by muse, mutect2, varscan2
- ISX | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 133/404 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as rs771619655; called by muse, mutect2, varscan2
- L1CAM | c.2174G>A p.G725E | Missense Mutation (SNP) | VAF 115/402 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100649507; called by muse, mutect2, varscan2
- LMAN1 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 102/278 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs372387855; called by muse, mutect2, varscan2
- LNX1 | c.676C>T p.R226* (on ENST00000263925 / NM_001126328.3; = p.R130* on NM_032622.2) | Nonsense Mutation (SNP) | VAF 114/341 reads (33%) | catalogued as rs776122418, COSV55790771; called by muse, mutect2, varscan2
- LOXHD1 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 92/309 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1294424921, COSV59661575; called by muse, mutect2, varscan2
- LRPPRC | c.2998C>T p.L1000F | Missense Mutation (SNP) | VAF 74/254 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV53241755; called by muse, mutect2, varscan2
- LZTS2 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 114/437 reads (26%) | catalogued as rs1299621526; called by muse, varscan2
- MDGA1 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 96/413 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.427); catalogued as rs1243452471, COSV99777283; called by muse, mutect2, varscan2
- MMP16 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 98/331 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV54150706, COSV54169162; called by muse, mutect2, varscan2
- MTPAP | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 103/355 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV53934548; called by muse, mutect2, varscan2
- MXRA5 | c.8281C>T p.P2761S | Missense Mutation (SNP) | VAF 196/618 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54223330; called by muse, mutect2, varscan2
- MYH6 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 118/395 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs765792077, COSV62452710; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NDRG1 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 329/646 reads (51%) | catalogued as COSV100106618; called by muse, mutect2, varscan2
- NMI | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs758506691; called by muse, mutect2, varscan2
- NRK | c.2193G>A p.W731* | Nonsense Mutation (SNP) | VAF 136/440 reads (31%) | catalogued as COSV54601995; called by muse, mutect2, varscan2
- NUP188 | c.4192C>T p.R1398C | Missense Mutation (SNP) | VAF 104/322 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as rs1214820198, COSV65340095; called by muse, mutect2, varscan2
- OR4K3 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 92/289 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as rs942553632; called by muse, mutect2, varscan2
- OR8H3 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 137/473 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57908231; called by muse, mutect2, varscan2
- PASD1 | c.1215G>A p.M405I | Missense Mutation (SNP) | VAF 105/320 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1434722032; called by muse, mutect2, varscan2
- PCDHA13 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 76/291 reads (26%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.139); catalogued as rs868963567, COSV56502477; called by muse, mutect2, varscan2
- PCDHAC2 | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 134/424 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs782146005, COSV53847785; called by muse, mutect2, varscan2
- PCDHGA8 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 99/297 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.327); catalogued as COSV53997627; called by muse, mutect2, varscan2
- PLPPR1 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 92/313 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV66454401; called by muse, mutect2, varscan2
- POTEG | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 47/499 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764838503, COSV73512509; called by muse, mutect2
- PPP1R26 | c.3116C>T p.P1039L | Missense Mutation (SNP) | VAF 173/546 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.148); catalogued as rs910126651, COSV63354868; called by muse, mutect2, varscan2
- PSG6 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 254/597 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.17); catalogued as COSV51830662, COSV99413742; called by muse, mutect2, varscan2
- PTEN | c.924_925dup p.A309Vfs*9 | Frame Shift Ins (INS) | VAF 83/216 reads (38%) | catalogued as COSV64307905, COSV64310627; called by mutect2, pindel, varscan2
- RGS7 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 92/370 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58542235; called by muse, mutect2, varscan2
- ROR2 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 124/428 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs186571882, COSV65217266; called by muse, mutect2, varscan2
- RP1 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 293/515 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV55126344; called by muse, mutect2, varscan2
- S1PR4 | c.781C>G p.L261V | Missense Mutation (SNP) | VAF 172/743 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV55741584; called by muse, mutect2, varscan2
- SCAF4 | c.2705C>T p.P902L | Missense Mutation (SNP) | VAF 132/468 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV54255565; called by muse, mutect2, varscan2
- SELL | c.764G>A p.G255E (on ENST00000650983; = p.G242E on NM_000655.5) | Missense Mutation (SNP) | VAF 164/340 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.166); catalogued as COSV52549777; called by muse, mutect2, varscan2
- SLITRK6 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 113/360 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1359554472, COSV101233285, COSV68390167; called by muse, mutect2, varscan2
- SMARCA4 | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 16/496 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60791074; called by muse, mutect2
- SULT2B1 | c.716C>T p.S239F (on ENST00000201586 / NM_177973.2; = p.S224F on NM_004605.2) | Missense Mutation (SNP) | VAF 272/559 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1407815723, COSV99572120; called by muse, mutect2, varscan2
- TACR1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.023); catalogued as rs1003492126; called by muse, mutect2, varscan2
- TBC1D10A | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 161/540 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs754413591; called by muse, mutect2, varscan2
- TEX52 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 134/422 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs926304579; called by muse, mutect2, varscan2
- TGFBR2 | c.1160T>G p.V387G | Missense Mutation (SNP) | VAF 145/423 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55442962; called by muse, mutect2, varscan2
- TMC5 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 89/279 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs748742122; called by muse, mutect2, varscan2
- TMEM232 | c.1589C>T p.P530L | Missense Mutation (SNP) | VAF 79/247 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs112074804; called by muse, mutect2, varscan2
- TTN | c.47875G>A p.E15959K (on ENST00000591111; = p.E8535K on NM_003319.4) | Missense Mutation (SNP) | VAF 126/383 reads (33%) | PolyPhen benign (0.359); catalogued as rs745629273, COSV59970551; called by muse, mutect2, varscan2
- UGT2B11 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 87/298 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs775064565, COSV71423283; called by muse, mutect2, varscan2
- XCR1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 110/461 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs181024730, COSV58569755; called by muse, mutect2, varscan2
- ZNF665 | c.1357G>C p.E453Q (on ENST00000600412; = p.E518Q on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 134/448 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV67214976; called by muse, mutect2
- ZNF711 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.478); catalogued as COSV52153375; called by muse, mutect2
- ZNF722P | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 91/269 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.783); catalogued as rs751396764; called by muse, mutect2, varscan2
- ZNHIT1 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 104/435 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1364666223, COSV59313115; called by muse, mutect2, varscan2
- ADAM29 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 123/399 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ANK3 | c.6294G>A p.M2098I | Missense Mutation (SNP) | VAF 109/233 reads (47%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP3D1 | c.455T>G p.M152R | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- APC | c.7445C>T p.P2482L | Missense Mutation (SNP) | VAF 109/340 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP18 | c.235dup p.W79Lfs*11 | Frame Shift Ins (INS) | VAF 84/319 reads (26%) | called by mutect2, pindel, varscan2
- CCDC185 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 311/652 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- CCDC58 | c.23T>G p.V8G | Missense Mutation (SNP) | VAF 16/522 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- CFAP92 | c.1534C>T p.H512Y | Missense Mutation (SNP) | VAF 87/296 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CT47B1 | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 215/722 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DTX2 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 228/544 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, varscan2
- EDA | c.1022C>T p.T341I | Missense Mutation (SNP) | VAF 194/578 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- EDEM1 | c.904T>C p.C302R | Missense Mutation (SNP) | VAF 78/248 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ENAM | c.360A>C p.Q120H | Missense Mutation (SNP) | VAF 157/489 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- EPPK1 | c.1828G>A p.G610S | Missense Mutation (SNP) | VAF 375/669 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ERVV-2 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 179/334 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR101 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 175/584 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HAS1 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 163/790 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- HS1BP3 | c.228G>C p.E76D | Missense Mutation (SNP) | VAF 118/346 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- HYDIN | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- IGF1 | c.400A>C p.K134Q | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- KCNIP2 | c.94A>T p.K32* | Nonsense Mutation (SNP) | VAF 93/349 reads (27%) | called by muse, mutect2, varscan2
- LIFR | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC53 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 179/300 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- LRRC53 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 180/301 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MALRD1 | c.3046G>A p.D1016N | Missense Mutation (SNP) | VAF 75/276 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED13 | c.3175C>G p.P1059A | Missense Mutation (SNP) | VAF 113/461 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NPSR1 | c.199A>T p.N67Y | Missense Mutation (SNP) | VAF 194/407 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUDT12 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- OR4D2 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 209/466 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- PRELP | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 127/555 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- PRKD3 | c.835del p.Y279Tfs*14 | Frame Shift Del (DEL) | VAF 102/367 reads (28%) | called by mutect2, pindel, varscan2
- PRR32 | c.647G>A p.R216K | Missense Mutation (SNP) | VAF 201/592 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PTK2 | c.1252C>T p.Q418* | Nonsense Mutation (SNP) | VAF 58/399 reads (15%) | called by muse, mutect2, varscan2
- PTPN20 | c.563G>A p.R188K | Missense Mutation (SNP) | VAF 86/139 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RGPD4 | c.2984G>A p.G995E | Missense Mutation (SNP) | VAF 90/409 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- RGS22 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 64/378 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SAP130 | c.1220C>T p.T407I | Missense Mutation (SNP) | VAF 68/285 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- SCN7A | c.842A>G p.N281S | Missense Mutation (SNP) | VAF 92/270 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- SEMG2 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 89/311 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SERPINA4 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 90/307 reads (29%) | SIFT tolerated (0.91); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- SH3RF2 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 122/389 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHROOM1 | c.2525C>T p.P842L (on ENST00000378679 / NM_001172700.2; = p.P837L on NM_133456.2) | Missense Mutation (SNP) | VAF 116/396 reads (29%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SHROOM4 | c.4100T>G p.L1367W | Missense Mutation (SNP) | VAF 148/521 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SORL1 | c.1837C>T p.L613F | Missense Mutation (SNP) | VAF 89/211 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- TBL1XR1 | c.938A>T p.D313V | Missense Mutation (SNP) | VAF 90/272 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- THOC2 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TM4SF5 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 82/261 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TMEM237 | c.227C>T p.P76L (on ENST00000409883 / NM_001044385.3; = p.P68L on NM_152388.4) | Missense Mutation (SNP) | VAF 103/326 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMEM26 | c.720G>C p.R240S | Missense Mutation (SNP) | VAF 99/204 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- TMEM52 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- TNP2 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 163/457 reads (36%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TPBGL | c.176A>G p.D59G | Missense Mutation (SNP) | VAF 147/311 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- TRPC5 | c.1064A>G p.N355S | Missense Mutation (SNP) | VAF 153/529 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSSK1B | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 124/334 reads (37%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- UNC13C | c.4747G>A p.G1583R | Missense Mutation (SNP) | VAF 94/298 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC5A | c.523G>A p.G175S | Missense Mutation (SNP) | VAF 98/295 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP33 | c.2357T>G p.L786R | Missense Mutation (SNP) | VAF 138/244 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- VLDLR | c.327T>C p.H109= | Splice Region (SNP) | VAF 70/148 reads (47%) | called by muse, mutect2, varscan2
- ZBTB34 | c.1288T>G p.C430G | Missense Mutation (SNP) | VAF 137/454 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF778 | c.1634C>T p.S545F | Missense Mutation (SNP) | VAF 98/324 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.661); called by muse, mutect2
- ACLY | c.330C>T p.F110= | Silent (SNP) | VAF 148/345 reads (43%) | catalogued as rs146805244; called by muse, mutect2, varscan2
- ARHGEF19 | c.1533C>T p.F511= | Silent (SNP) | VAF 216/350 reads (62%) | catalogued as COSV99580638; called by muse, mutect2, varscan2
- ATP2A3 | c.2358C>T p.A786= | Silent (SNP) | VAF 94/306 reads (31%) | called by muse, mutect2, varscan2
- BTNL2 | c.1203G>A p.T401= | Silent (SNP) | VAF 155/668 reads (23%) | catalogued as rs759428218, COSV66630771; called by muse, mutect2, varscan2
- CCDC114 | c.678C>T p.F226= | Silent (SNP) | VAF 134/520 reads (26%) | catalogued as rs867613985; called by muse, mutect2, varscan2
- CCS | c.315C>T p.F105= | Silent (SNP) | VAF 132/430 reads (31%) | catalogued as rs1435644135, COSV59580335; called by muse, mutect2, varscan2
- CD96 | c.903C>T p.I301= (on ENST00000283285 / NM_198196.3; = p.I285= on NM_005816.5) | Silent (SNP) | VAF 44/193 reads (23%) | catalogued as rs267599541, COSV51915405; called by muse, mutect2, varscan2
- CEP170B | c.3909G>A p.R1303= (on ENST00000453495; = p.R1232= on NM_015005.3) | Silent (SNP) | VAF 181/489 reads (37%) | called by muse, mutect2, varscan2
- COL17A1 | c.243G>A p.R81= | Silent (SNP) | VAF 96/274 reads (35%) | called by muse, mutect2, varscan2
- CSMD3 | c.10017T>C p.G3339= (on ENST00000297405 / NM_001363185.1; = p.G3170= on NM_052900.3) | Silent (SNP) | VAF 89/479 reads (19%) | catalogued as rs1450187817; called by muse, mutect2, varscan2
- DNAH8 | c.6750C>T p.N2250= | Silent (SNP) | VAF 104/492 reads (21%) | called by muse, mutect2, varscan2
- EFCAB6 | c.3963C>T p.I1321= | Silent (SNP) | VAF 108/356 reads (30%) | called by muse, mutect2, varscan2
- EYA1 | c.102C>T p.S34= | Silent (SNP) | VAF 54/337 reads (16%) | called by muse, mutect2, varscan2
- FAHD2B | c.444C>T p.V148= | Silent (SNP) | VAF 52/213 reads (24%) | called by muse, mutect2, varscan2
- FMN2 | c.3825G>A p.G1275= | Silent (SNP) | VAF 114/475 reads (24%) | catalogued as COSV60441644; called by muse, mutect2, varscan2
- FRK | c.1278C>T p.I426= | Silent (SNP) | VAF 72/247 reads (29%) | catalogued as COSV101606679; called by muse, mutect2, varscan2
- INPPL1 | c.3327C>T p.F1109= | Silent (SNP) | VAF 326/734 reads (44%) | catalogued as rs756299036; called by muse, mutect2, varscan2
- KLK12 | c.657G>A p.V219= | Silent (SNP) | VAF 149/620 reads (24%) | called by muse, mutect2, varscan2
- KNDC1 | c.2403G>A p.P801= | Silent (SNP) | VAF 212/666 reads (32%) | catalogued as rs770815663; called by muse, mutect2
- LARP6 | c.381G>A p.V127= | Silent (SNP) | VAF 92/305 reads (30%) | catalogued as COSV54581262; called by muse, mutect2, varscan2
- LMO7 | c.93T>C p.G31= (on ENST00000357063; = p.G46= on NM_005358.5) | Silent (SNP) | VAF 93/313 reads (30%) | catalogued as rs1392502615; called by muse, mutect2, varscan2
- LOXHD1 | c.4797C>T p.I1599= | Silent (SNP) | VAF 128/412 reads (31%) | catalogued as rs1175532322, COSV56070162; called by muse, mutect2, varscan2
- LRRC7 | c.1404G>A p.Q468= (on ENST00000651989 / NM_001370785.2; = p.Q435= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 133/220 reads (60%) | catalogued as rs1443850172; called by muse, mutect2, varscan2
- LRRTM3 | c.1641G>A p.T547= | Silent (SNP) | VAF 103/246 reads (42%) | catalogued as rs544274000, COSV63670030; called by muse, mutect2, varscan2
- MUC5B | c.435C>T p.N145= | Silent (SNP) | VAF 77/334 reads (23%) | catalogued as rs747683160, COSV71594620; called by muse, mutect2, varscan2
- NAA11 | c.300G>A p.E100= | Silent (SNP) | VAF 124/364 reads (34%) | called by muse, mutect2, varscan2
- NACAD | c.3813A>G p.P1271= | Silent (SNP) | VAF 153/583 reads (26%) | catalogued as rs1391534875; called by muse, mutect2, varscan2
- NLGN2 | c.1911C>G p.A637= | Silent (SNP) | VAF 192/651 reads (29%) | called by muse, mutect2, varscan2
- NLRP14 | c.2349C>T p.I783= | Silent (SNP) | VAF 105/328 reads (32%) | catalogued as rs1342485400; called by muse, mutect2, varscan2
- OR2T6 | c.336C>T p.F112= | Silent (SNP) | VAF 359/827 reads (43%) | catalogued as COSV63217117; called by muse, mutect2, varscan2
- OR5L2 | c.127C>T p.L43= | Silent (SNP) | VAF 146/429 reads (34%) | catalogued as COSV65725463; called by muse, mutect2, varscan2
- OVCH2 | c.595C>T p.L199= | Silent (SNP) | VAF 28/430 reads (7%) | called by muse, mutect2
- PITPNM3 | c.1068C>T p.H356= | Silent (SNP) | VAF 82/290 reads (28%) | called by muse, mutect2, varscan2
- PLCB1 | c.1293C>T p.I431= | Silent (SNP) | VAF 116/365 reads (32%) | called by muse, mutect2, varscan2
- PLCL2 | c.3198C>T p.I1066= (on ENST00000615277 / NM_001144382.2; = p.I940= on NM_015184.5) | Silent (SNP) | VAF 69/188 reads (37%) | called by muse, mutect2, varscan2
- PLEC | c.10200T>G p.T3400= (on ENST00000322810 / NM_201380.4; = p.T3290= on NM_000445.5) | Silent (SNP) | VAF 247/670 reads (37%) | called by muse, mutect2, varscan2
- PREX2 | c.1683C>T p.F561= | Silent (SNP) | VAF 182/461 reads (39%) | called by mutect2, varscan2
- PRKACG | c.564C>T p.F188= | Silent (SNP) | VAF 187/539 reads (35%) | catalogued as rs753540473, COSV55251529; called by muse, mutect2, varscan2
- PTPRM | c.2646G>A p.V882= | Silent (SNP) | VAF 135/372 reads (36%) | catalogued as COSV100156591; called by muse, mutect2, varscan2
- RASSF4 | c.966A>G p.*322= | Silent (SNP) | VAF 100/312 reads (32%) | called by muse, mutect2, varscan2
- RFX6 | c.1728C>A p.A576= | Silent (SNP) | VAF 107/381 reads (28%) | called by muse, mutect2, varscan2
- RP1 | c.639C>T p.I213= | Silent (SNP) | VAF 69/447 reads (15%) | catalogued as rs267601948, COSV55121216; called by muse, mutect2, varscan2
- RPA4 | c.393C>T p.L131= | Silent (SNP) | VAF 128/413 reads (31%) | called by muse, mutect2, varscan2
- RTL3 | c.519C>T p.Y173= | Silent (SNP) | VAF 171/523 reads (33%) | called by muse, mutect2, varscan2
- SALL4 | c.2367C>T p.S789= | Silent (SNP) | VAF 112/368 reads (30%) | catalogued as COSV53849645; called by muse, mutect2, varscan2
- SCAPER | c.471A>G p.L157= | Silent (SNP) | VAF 86/261 reads (33%) | catalogued as rs1178805765; called by muse, mutect2, varscan2
- SEMA3E | c.2007C>T p.T669= | Silent (SNP) | VAF 89/405 reads (22%) | catalogued as rs1275768724; called by muse, mutect2, varscan2
- SERPINA10 | c.1317G>A p.V439= | Silent (SNP) | VAF 91/305 reads (30%) | catalogued as rs1162068079, COSV56229550; called by muse, mutect2, varscan2
- SNAP91 | c.444G>A p.V148= | Silent (SNP) | VAF 75/241 reads (31%) | catalogued as COSV52119280; called by muse, mutect2, varscan2
- SPEM3 | c.1617C>T p.S539= | Silent (SNP) | VAF 104/340 reads (31%) | catalogued as rs937441899; called by muse, mutect2, varscan2
- TAFA1 | c.54T>C p.C18= | Silent (SNP) | VAF 108/326 reads (33%) | called by muse, mutect2, varscan2
- TMC7 | c.477G>A p.G159= | Silent (SNP) | VAF 85/299 reads (28%) | catalogued as COSV58584385, COSV58584961; called by muse, mutect2, varscan2
- TRIM74 | c.747C>T p.S249= | Silent (SNP) | VAF 10/53 reads (19%) | called by mutect2, varscan2
- TRRAP | c.2166C>T p.S722= | Silent (SNP) | VAF 156/358 reads (44%) | catalogued as COSV62857171; called by muse, mutect2, varscan2
- TTN | c.897G>A p.P299= | Silent (SNP) | VAF 62/243 reads (26%) | called by muse, mutect2, varscan2
- ZNF217 | c.1806C>T p.F602= | Silent (SNP) | VAF 112/367 reads (31%) | called by muse, mutect2, varscan2
- RIMS2 | c.1692+328G>C | Intron (SNP) | VAF 64/302 reads (21%) | called by muse, mutect2, varscan2
- ST3GAL2 | c.-509C>T | 5'UTR (SNP) | VAF 80/251 reads (32%) | catalogued as rs981667419; called by muse, mutect2, varscan2
- TCF4 | c.305-191G>A | Intron (SNP) | VAF 73/217 reads (34%) | catalogued as rs762671791; called by muse, mutect2, varscan2
